Somatic mutation profile of tumor specimen MMRF_2143_1_BM_CD138pos (aliquot MMRF_2143_1_BM_CD138pos_T1_KHS5U_L08837) from MMRF case MMRF_2143, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Dead; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 64.4 years (23,535 days).
Specimen MMRF_2143_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0355cee2-d2b6-4238-8b41-a820abb00afa.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2143_1_PB_Whole (Blood Derived Normal), aliquot MMRF_2143_1_PB_Whole_C3_KHS5U_L08771; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f39eff56-7823-4496-b130-9156ab402529

The open-access MAF lists 78 somatic variants for this specimen: 35 protein-altering or splice-affecting, 12 silent, 31 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 32, 3'UTR 20, Silent 12, Intron 6, Splice Site 2, 5'Flank 2, RNA 1, 5'UTR 1, 3'Flank 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAMTS5 | c.509G>A p.R170H | Missense Mutation (SNP) | VAF 24/137 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.376); catalogued as rs1214733599, COSV53184219; called by muse, mutect2, varscan2
- CRYGN | c.347G>T p.S116I | Missense Mutation (SNP) | VAF 7/180 reads (4%) | SIFT tolerated (0.31); PolyPhen benign (0.049); catalogued as COSV61564016; called by muse, mutect2
- DLEC1 | c.1572+1G>A p.X524_splice | Splice Site (SNP) | VAF 10/131 reads (8%) | catalogued as rs1233618630; called by muse, mutect2
- DNAH17 | c.142G>A p.D48N | Missense Mutation (SNP) | VAF 22/139 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.043); catalogued as COSV101103170; called by muse, mutect2, varscan2
- GREM2 | c.95C>T p.S32L | Missense Mutation (SNP) | VAF 36/182 reads (20%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.775); catalogued as rs756394325; called by muse, mutect2, varscan2
- IGKJ5 | c.4A>C p.I2L | Missense Mutation (SNP) | VAF 35/192 reads (18%) | catalogued as rs374322906; called by muse, mutect2, varscan2
- IGLV3-1 | c.148T>A p.Y50N | Missense Mutation (SNP) | VAF 34/114 reads (30%) | SIFT tolerated (0.14); PolyPhen benign (0.03); catalogued as rs368495152; called by muse, varscan2
- KRBA1 | c.475G>A p.D159N | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT tolerated (0.17); PolyPhen benign (0.012); catalogued as rs759946924, COSV55440748, COSV55441896; called by muse, mutect2, varscan2
- NAALADL2 | c.1219G>A p.E407K | Missense Mutation (SNP) | VAF 20/107 reads (19%) | SIFT tolerated (0.68); PolyPhen benign (0.001); catalogued as COSV69153918; called by muse, mutect2, varscan2
- NUGGC | c.2315G>A p.R772Q | Missense Mutation (SNP) | VAF 27/190 reads (14%) | SIFT tolerated, low confidence (0.72); PolyPhen benign (0); catalogued as rs763797956, COSV58432435; called by muse, mutect2, varscan2
- PCDH12 | c.2279G>A p.R760H | Missense Mutation (SNP) | VAF 39/236 reads (17%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.899); catalogued as rs139572685; called by muse, mutect2, varscan2
- PCDHGA5 | c.185G>A p.R62H | Missense Mutation (SNP) | VAF 16/85 reads (19%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.104); catalogued as COSV53928338; called by muse, mutect2, varscan2
- POF1B | c.358-2A>C p.X120_splice | Splice Site (SNP) | VAF 7/34 reads (21%) | catalogued as rs746282684; called by muse, mutect2, varscan2
- TGFBI | c.1189C>A p.Q397K | Missense Mutation (SNP) | VAF 24/143 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.253); catalogued as rs1306941217; called by muse, mutect2, varscan2
- ASXL1 | c.110_114del p.V37Gfs*35 | Frame Shift Del (DEL) | VAF 24/173 reads (14%) | called by mutect2, pindel, varscan2
- C2CD4C | c.121G>T p.V41L | Missense Mutation (SNP) | VAF 7/182 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.934); called by muse, mutect2
- CABYR | c.299A>G p.E100G | Missense Mutation (SNP) | VAF 84/415 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- COL4A2 | c.3461C>T p.P1154L | Missense Mutation (SNP) | VAF 7/100 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.837); called by muse, mutect2
- FARSA | c.407T>G p.V136G | Missense Mutation (SNP) | VAF 72/226 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.714); called by muse, mutect2, varscan2
- FASTKD5 | c.700C>T p.H234Y | Missense Mutation (SNP) | VAF 9/93 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.171); called by muse, mutect2
- FAT4 | c.11397G>T p.K3799N | Missense Mutation (SNP) | VAF 27/141 reads (19%) | SIFT tolerated (0.16); PolyPhen benign (0.133); called by muse, mutect2, varscan2
- MYH6 | c.5196G>T p.M1732I | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT deleterious (0.05); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- NFASC | c.678G>C p.K226N (on ENST00000339876 / NM_001378329.1; = p.K220N on NM_015090.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/152 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR8G1 | c.384C>A p.S128R | Missense Mutation (SNP) | VAF 7/190 reads (4%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.005); called by muse, mutect2
- PIWIL2 | c.367C>G p.P123A | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0); called by muse, mutect2, varscan2
- RAET1L | c.616G>A p.E206K | Missense Mutation (SNP) | VAF 16/184 reads (9%) | SIFT tolerated (0.68); PolyPhen benign (0.224); called by muse, mutect2
- RCC1L | c.227C>T p.S76F | Missense Mutation (SNP) | VAF 7/136 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.694); called by muse, mutect2
- SNCB | c.140G>C p.G47A | Missense Mutation (SNP) | VAF 22/165 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.923); called by muse, mutect2, varscan2
- TENT5C | c.454T>A p.W152R | Missense Mutation (SNP) | VAF 8/126 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- TRIM55 | c.829T>G p.F277V | Missense Mutation (SNP) | VAF 28/193 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- UBR5 | c.8206A>G p.S2736G | Missense Mutation (SNP) | VAF 18/108 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- VPS8 | c.655G>C p.A219P (on ENST00000625842 / NM_001349294.1; = p.A217P on NM_015303.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/98 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- XCL1 | c.13A>C p.I5L | Missense Mutation (SNP) | VAF 26/364 reads (7%) | SIFT tolerated (0.7); PolyPhen benign (0); called by muse, mutect2
- ZNF609 | c.4064G>A p.R1355H | Missense Mutation (SNP) | VAF 18/195 reads (9%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.799); called by muse, mutect2
- ZNF724 | c.1366G>A p.G456S | Missense Mutation (SNP) | VAF 8/139 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.808); called by muse, mutect2
- AP1AR | c.798T>C p.S266= | Silent (SNP) | VAF 10/233 reads (4%) | catalogued as COSV56770031; called by muse, mutect2
- FZD3 | c.888T>C p.F296= | Silent (SNP) | VAF 11/103 reads (11%) | catalogued as rs1452733576, COSV104382818; called by muse, varscan2
- G2E3 | c.1293A>G p.S431= | Silent (SNP) | VAF 3/39 reads (8%) | called by muse, mutect2
- LAMC3 | c.4338G>A p.A1446= | Silent (SNP) | VAF 23/147 reads (16%) | catalogued as rs375730811; ClinVar: likely benign; called by muse, mutect2, varscan2
- MYH2 | c.5160G>A p.Q1720= | Silent (SNP) | VAF 9/123 reads (7%) | catalogued as COSV55438333, COSV99821250; called by muse, mutect2
- NAIF1 | c.135T>C p.S45= | Silent (SNP) | VAF 31/212 reads (15%) | called by muse, mutect2, varscan2
- PLAG1 | c.528G>A p.S176= | Silent (SNP) | VAF 9/111 reads (8%) | catalogued as rs374803048; called by muse, mutect2
- PLIN5 | c.357G>A p.K119= | Silent (SNP) | VAF 12/277 reads (4%) | catalogued as COSV67851032; called by muse, mutect2
- PRAG1 | c.1386C>T p.D462= | Silent (SNP) | VAF 16/112 reads (14%) | catalogued as rs1418280129; called by muse, mutect2, varscan2
- SOGA1 | c.1752C>T p.S584= | Silent (SNP) | VAF 7/145 reads (5%) | catalogued as COSV99415921; called by muse, mutect2
- SPATA31E1 | c.2337C>A p.G779= | Silent (SNP) | VAF 43/191 reads (23%) | catalogued as rs1221238803, COSV100350416; called by muse, mutect2, varscan2
- TAF1B | c.1761A>T p.R587= | Silent (SNP) | VAF 18/161 reads (11%) | called by muse, mutect2, varscan2
- AC027612.1 | n.776T>G | RNA (SNP) | VAF 5/37 reads (14%) | called by muse, mutect2, varscan2
- ADGRV1 | c.*13C>A | 3'UTR (SNP) | VAF 26/441 reads (6%) | called by muse, mutect2
- AL162726.3 | n.255+83326G>T | Intron (SNP) | VAF 15/155 reads (10%) | called by muse, mutect2, varscan2
- DRD5 | c.*331C>T | 3'UTR (SNP) | VAF 8/233 reads (3%) | called by muse, mutect2
- FAM186B | chr12:49584446 C>G | 3'Flank (SNP) | VAF 10/98 reads (10%) | called by muse, mutect2
- FGD2 | c.527+17G>A | Intron (SNP) | VAF 16/65 reads (25%) | catalogued as rs753995514; called by muse, mutect2, varscan2
- FNBP4 | c.*44G>A | 3'UTR (SNP) | VAF 8/189 reads (4%) | called by muse, mutect2
- FRAS1 | c.5857-302C>T | Intron (SNP) | VAF 3/49 reads (6%) | called by muse, mutect2
- GLCCI1 | c.*516T>C | 3'UTR (SNP) | VAF 6/60 reads (10%) | called by muse, mutect2, varscan2
- GRIK3 | c.*231G>A | 3'UTR (SNP) | VAF 13/81 reads (16%) | called by muse, mutect2, varscan2
- HSPA9 | c.-66C>A | 5'UTR (SNP) | VAF 30/125 reads (24%) | called by muse, mutect2, varscan2
- INPP5J | c.1494+63C>A | Intron (SNP) | VAF 19/97 reads (20%) | called by muse, mutect2, varscan2
- LGSN | c.*17A>C | 3'UTR (SNP) | VAF 8/53 reads (15%) | called by muse, mutect2, varscan2
- MGAT4C | c.*460C>G | 3'UTR (SNP) | VAF 8/57 reads (14%) | called by muse, mutect2, varscan2
- MGAT4C | c.*215A>G | 3'UTR (SNP) | VAF 16/76 reads (21%) | called by muse, varscan2
- MX2 | c.-72+1690G>A | Intron (SNP) | VAF 7/184 reads (4%) | called by muse, mutect2
- MYOZ2 | c.*361A>G | 3'UTR (SNP) | VAF 7/117 reads (6%) | called by muse, mutect2
- NAA10 | c.*656A>G | 3'UTR (SNP) | VAF 18/39 reads (46%) | called by muse, mutect2, varscan2
- PCARE | c.*234C>A | 3'UTR (SNP) | VAF 11/152 reads (7%) | called by muse, mutect2
- PPP1R9A | c.*537C>T | 3'UTR (SNP) | VAF 7/74 reads (9%) | catalogued as rs952903115; called by muse, mutect2
- PPP3CA | chr4:101348266 T>G | 5'Flank (SNP) | VAF 9/46 reads (20%) | called by muse, mutect2, varscan2
- PRDM1 | c.*278A>G | 3'UTR (SNP) | VAF 7/78 reads (9%) | called by muse, mutect2
- PSD3 | c.*8260A>G | 3'UTR (SNP) | VAF 28/90 reads (31%) | catalogued as rs1323032952; called by muse, mutect2, varscan2
- RNASE11 | chr14:20590164 G>A | 5'Flank (SNP) | VAF 26/134 reads (19%) | called by muse, mutect2, varscan2
- RTL5 | c.*1363A>C | 3'UTR (SNP) | VAF 5/25 reads (20%) | called by muse, mutect2, varscan2
- RUNX1T1 | c.*5148C>T | 3'UTR (SNP) | VAF 6/94 reads (6%) | catalogued as rs913952424; called by muse, mutect2
- SMIM3 | c.*13A>T | 3'UTR (SNP) | VAF 4/72 reads (6%) | called by muse, mutect2
- SSTR1 | c.*2122A>C | 3'UTR (SNP) | VAF 19/64 reads (30%) | called by muse, mutect2, varscan2
- TEK | c.*529T>G | 3'UTR (SNP) | VAF 9/123 reads (7%) | called by muse, mutect2
- UBXN10 | c.*4608T>A | 3'UTR (SNP) | VAF 4/53 reads (8%) | called by muse, mutect2
- XIRP2 | c.10030+100C>G | Intron (SNP) | VAF 4/54 reads (7%) | called by muse, mutect2
